Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFN, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFN-01A (Primary Tumor).

Department of Pathology

Direct dial -

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; nonseminoma (EC 100%); diameter 3 cm; tumor confined to the testis;
angioinvasion present; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Carcinoma, embryonal NOS
9670/3
Site: R Testis NOS
C62.9
Op J 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file d8a50b19-22f4-410a-974e-f3501a31e0ef (TCGA-2G-AAFN.8A8CDABC-55F1-4AFF-BE71-8B5FC7E0C96E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).